Somatic mutation profile of tumor specimen MP2PRT-PAUCHB-TMP1-A (aliquot MP2PRT-PAUCHB-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUCHB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,189 days).
Specimen MP2PRT-PAUCHB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b34a663-14e8-4e7c-8e96-5a3e143f27fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCHB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCHB-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63cc9593-66d7-4783-a120-fddf8d1d9013

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 25/381 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- BRSK2 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 87/605 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1189934116; called by muse, mutect2, varscan2
- DMBT1 | c.7441C>T p.R2481C (on ENST00000338354 / NM_001377530.1; = p.R1724C on NM_004406.3) | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1034308642, COSV57533768; called by muse, mutect2
- DYNC2H1 | c.6829C>G p.P2277A | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs1350586732; called by muse, mutect2, varscan2
- KDM2A | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 171/385 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs770605210; called by muse, mutect2, varscan2
- MKRN2OS | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); catalogued as rs756617395; called by muse, mutect2
- MROH2B | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs746281100, COSV68186680; called by muse, mutect2, varscan2
- RPTN | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 153/395 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs748176862; called by muse, mutect2, varscan2
- EPOR | c.1262_1263insG p.A422Cfs*4 | Frame Shift Ins (INS) | VAF 73/541 reads (13%) | called by mutect2, pindel, varscan2
- GPR149 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- UPP1 | c.102C>G p.L34= | Silent (SNP) | VAF 99/269 reads (37%) | called by muse, mutect2, varscan2
